Gene-level copy-number profile of tumor specimen TCGA-FR-A726-01A from TCGA case TCGA-FR-A726, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Lentigo maligna melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-FR-A726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.3a9c7ef7-e6ba-4e64-9b00-42e491823b09.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FR-A726-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a4b7e5f5-2687-4f1b-911f-aac0c90a2508

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 6,373; copy number 2: 45,889; copy number 3: 5,561; copy number 4: 1,903; copy number 6: 5; copy number 7: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FR-A726-01A-11D-A32M-01): tumor purity 0.7, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–23,438,700, 70 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:38,845,858–40,269,719, 16 genes, copy number 6–7 (within-gene range 4–7): OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P.

Autosomal genes at a single copy (total copy number 1): 4,220. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
